Somatic mutation profile of tumor specimen 0DQ2NE from CCDI case PBCELG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.3 years (4,873 days).
Specimen 0DQ2NE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5191783-c552-42ad-aeda-c76623e1d30f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQ2P1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9f92acb-3622-40a4-b2a1-35f66564f6de

The open-access MAF lists 26 somatic variants for this specimen: 11 protein-altering or splice-affecting, 7 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 7, 5'UTR 3, 3'UTR 2, 5'Flank 1, Splice Site 1, Nonsense Mutation 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK | c.11908G>A p.V3970I | Missense Mutation (SNP) | VAF 174/381 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140560498, COSV57228900; called by muse, mutect2, varscan2
- FUT5 | c.230T>A p.L77Q | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV53138945; called by mutect2, varscan2
- KSR1 | c.1241C>T p.P414L (on ENST00000644974 / NM_001367810.1; = p.P277L on NM_014238.2) | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.232); catalogued as rs560169479; called by muse, mutect2, varscan2
- MFAP3L | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 141/265 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1055702833; called by muse, mutect2, varscan2
- SNAP23 | c.626T>C p.I209T | Missense Mutation (SNP) | VAF 162/408 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.911); catalogued as rs1285002345; called by muse, mutect2, varscan2
- AKR1B15 | c.637-2A>C p.X213_splice | Splice Site (SNP) | VAF 159/441 reads (36%) | called by muse, mutect2, varscan2
- GRID1 | c.73C>G p.H25D | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- MRPS23 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 124/451 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PYROXD1 | c.1363C>T p.R455* | Nonsense Mutation (SNP) | VAF 123/389 reads (32%) | called by muse, mutect2, varscan2
- SP9 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SPATA20 | c.1295A>G p.H432R (on ENST00000356488 / NM_001258372.1; = p.H448R on NM_022827.4) | Missense Mutation (SNP) | VAF 67/376 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CGREF1 | c.471T>C p.A157= | Silent (SNP) | VAF 107/226 reads (47%) | called by muse, mutect2, varscan2
- CRACDL | c.549C>T p.V183= | Silent (SNP) | VAF 16/280 reads (6%) | catalogued as rs953441703, COSV67409990; called by muse, mutect2
- PARD3B | c.3027A>T p.P1009= (on ENST00000406610 / NM_001302769.2; = p.P940= on NM_057177.7) | Silent (SNP) | VAF 115/244 reads (47%) | catalogued as rs1559096596; called by muse, mutect2, varscan2
- PCDH18 | c.2706C>T p.S902= | Silent (SNP) | VAF 94/345 reads (27%) | catalogued as rs757986991; called by muse, mutect2, varscan2
- RYR2 | c.3360T>C p.P1120= | Silent (SNP) | VAF 354/531 reads (67%) | called by muse, mutect2, varscan2
- TNS3 | c.1668G>A p.G556= | Silent (SNP) | VAF 93/334 reads (28%) | called by muse, mutect2, varscan2
- UNC5C | c.1908G>A p.V636= | Silent (SNP) | VAF 85/191 reads (45%) | called by muse, mutect2, varscan2
- ANK1 | c.-20C>A | 5'UTR (SNP) | VAF 99/212 reads (47%) | called by muse, mutect2, varscan2
- ANKH | c.*10C>T | 3'UTR (SNP) | VAF 68/146 reads (47%) | catalogued as rs750571370; called by muse, mutect2, varscan2
- FDXR | c.271-44C>A | Intron (SNP) | VAF 54/94 reads (57%) | called by muse, mutect2, varscan2
- KDM1A | c.-72G>T | 5'UTR (SNP) | VAF 27/61 reads (44%) | called by muse, mutect2, varscan2
- SCN1B | c.-8G>A | 5'UTR (SNP) | VAF 53/136 reads (39%) | called by muse, mutect2, varscan2
- SGK1 | chr6:134175587 G>C | 5'Flank (SNP) | VAF 99/216 reads (46%) | catalogued as rs917768143; called by muse, mutect2, varscan2
- SLC19A3 | c.*16C>T | 3'UTR (SNP) | VAF 97/201 reads (48%) | catalogued as rs199499719, COSV99295543; called by muse, mutect2, varscan2
- SYNE2 | chr14:64227479 G>A | 3'Flank (SNP) | VAF 80/168 reads (48%) | catalogued as rs1193614559; called by muse, mutect2
